Gene-level copy-number profile of tumor specimen TCGA-CN-6997-01A from TCGA case TCGA-CN-6997, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 66.5 years (24,298 days).
Specimen TCGA-CN-6997-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.0708217f-f715-4c51-90d5-ed8e934d0249.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-6997-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1bfdb6b6-b9db-4c3a-97e1-ab4e5e5e7f57

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 22,125; copy number 2: 31,584; copy number 3: 4,975; copy number 4: 490; copy number 5: 375; copy number 6: 172; copy number 7: 20; copy number 17: 34; copy number 20: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-6997-01A-11D-2010-01): tumor purity 0.81, ploidy 1.76, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:86,336,318–86,815,171, 3 genes (within-gene range 0–1): RN7SKP96, MIR4452, PTPN13.
- chr8:3,373,353–4,329,027, 4 genes: AC026991.1, AC026991.2, RNA5SP251, AC027251.1.
- chr18:13,217,498–13,652,755, 1 gene (within-gene range 0–1): LDLRAD4.
- chr18:13,279,415–13,472,709, 6 genes: AP002505.2, AP002439.1, LDLRAD4-AS1, MIR5190, AP005131.5, AP005131.4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 617 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:175,369,540–187,078,553, 252 genes, copy number 5 (broad region; genes not listed).
- chr7:54,185,071–57,425,676, 133 genes, copy number 5–20 (broad region; genes not listed).
- chr7:71,779,491–72,447,151, 1 gene, copy number 5 (within-gene range 3–5): CALN1.
- chr7:72,558,744–72,954,790, 11 genes, copy number 5: TYW1B, MIR4650-2, AC211469.2, AC211469.1, RN7SL377P, SBDSP1, RN7SL625P, SPDYE7P, POM121, AC211476.2, NSUN5P2.
- chr7:118,880,103–118,951,259, 2 genes, copy number 5: GTF3AP6, AC092098.1.
- chr11:62,116,470–62,393,412, 13 genes, copy number 5 (within-gene range 3–5): AP002793.1, INCENP, EEF1DP8, SCGB1D1, SCGB2A1, AP003306.1, SCGB1D2, SCGB2A2, SCGB1D4, NPM1P35, AP003306.2, ASRGL1, RCC2P6.
- chr11:69,467,598–70,436,584, 30 genes, copy number 5–7: AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,477,592, 1 gene, copy number 7: AP001271.1.
- chr14:21,749,178–23,119,255, 166 genes, copy number 6 (broad region; genes not listed).
- chr18:4,430,945–4,459,458, 2 genes, copy number 5: AP005208.1, ELOCP27.
- chr18:30,290,161–30,984,215, 6 genes, copy number 6: AC115100.1, MIR302F, AC090506.1, AC090506.2, AC016382.1, RNU6-857P.

Autosomal genes at a single copy (total copy number 1): 19,713. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
